Somatic mutation profile of tumor specimen TCGA-FN-7833-01A (aliquot TCGA-FN-7833-01A-11D-2086-08) from TCGA case TCGA-FN-7833, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 25.3 years (9,228 days).
Specimen TCGA-FN-7833-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fbeb9a8-bb2f-4f04-be85-6d74f26b1ab4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FN-7833-10A (Blood Derived Normal), aliquot TCGA-FN-7833-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d1c7dac-2db1-4da0-a2b7-b2ce57cae444

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Del 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 43/123 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ABCA13 | c.10249T>C p.F3417L | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV71290841; called by muse, mutect2, varscan2
- CCDC60 | c.322T>C p.Y108H | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.655); catalogued as COSV59546476; called by muse, mutect2
- CD46 | c.121T>C p.F41L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.974); catalogued as COSV59734137; called by muse, mutect2, varscan2
- DOCK8 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.846); catalogued as rs771347031, COSV66620313, COSV66621457; called by muse, mutect2, varscan2
- EXPH5 | c.2561C>T p.T854I | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.209); catalogued as COSV56204568; called by muse, mutect2, varscan2
- KPNA5 | c.372G>C p.Q124H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV62653220; called by muse, mutect2
- OR1M1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1292472845, COSV70036699; called by muse, mutect2, varscan2
- SPOP | c.563A>C p.D188A | Missense Mutation (SNP) | VAF 116/292 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV61654607; called by muse, mutect2, varscan2
- TP53 | c.454_455dup p.P153Rfs*18 | Frame Shift Ins (INS) | VAF 39/125 reads (31%) | catalogued as COSV53468298, COSV99394349; called by mutect2, pindel, varscan2
- ATRX | c.5817dup p.D1940Rfs*2 | Frame Shift Ins (INS) | VAF 166/292 reads (57%) | called by mutect2, pindel, varscan2
- LPAR1 | c.613_638del p.S205Qfs*30 | Frame Shift Del (DEL) | VAF 25/177 reads (14%) | called by mutect2, pindel
- NIPBL | c.6225del p.K2075Nfs*8 | Frame Shift Del (DEL) | VAF 37/112 reads (33%) | called by mutect2, pindel, varscan2
- COL4A5 | c.639A>T p.G213= | Silent (SNP) | VAF 21/23 reads (91%) | catalogued as COSV60365291; called by muse, mutect2, varscan2
- OR51F2 | c.195C>T p.L65= | Silent (SNP) | VAF 38/216 reads (18%) | catalogued as COSV59065269; called by muse, varscan2
- PRPF8 | c.5991G>A p.V1997= | Silent (SNP) | VAF 56/286 reads (20%) | catalogued as rs1260453598, COSV56773625; called by muse, mutect2, varscan2
